Somatic mutation profile of tumor specimen C3L-04331-01 (aliquot CPT0270410009) from CPTAC case C3L-04331, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 87.7 years (32,040 days).
Specimen C3L-04331-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f818061-006b-41d5-87cb-d3583fca1996.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04331-31 (Blood Derived Normal), aliquot CPT0270570002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad655d9e-1322-4160-ae50-b8520096441d

The open-access MAF lists 359 somatic variants for this specimen: 250 protein-altering or splice-affecting, 103 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 229, Silent 103, Nonsense Mutation 14, Splice Region 3, Intron 3, Frame Shift Del 2, 3'Flank 2, Frame Shift Ins 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/264 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDKN2A | c.249C>G p.H83Q | Missense Mutation (SNP) | VAF 66/473 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs34968276, CM056553, CM165739, COSV58684711, COSV58719805; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS20 | c.1133G>A p.G378D | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67126064; called by muse, mutect2
- AHNAK2 | c.13594C>T p.P4532S | Missense Mutation (SNP) | VAF 57/391 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV60924482; called by muse, mutect2, varscan2
- ALK | c.2416C>T p.R806C | Missense Mutation (SNP) | VAF 43/411 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs80227749, COSV66590467; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALMS1 | c.8033C>T p.P2678L | Missense Mutation (SNP) | VAF 38/432 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as CM1213436; called by muse, mutect2
- AMY1B | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 29/480 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.243); catalogued as COSV100375566; called by muse, mutect2
- ANP32E | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 25/280 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as rs1553840928; called by muse, mutect2
- AR | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 68/285 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV65952593, COSV65965052; called by muse, mutect2, varscan2
- ASXL3 | c.2557C>T p.P853S | Missense Mutation (SNP) | VAF 34/360 reads (9%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV52467899; called by muse, mutect2
- BEST4 | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 76/410 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV100944014; called by muse, mutect2, varscan2
- BMP5 | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 28/300 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV63701018; called by muse, mutect2
- BRD9 | c.1640C>T p.S547L | Missense Mutation (SNP) | VAF 58/493 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs1560888323; called by muse, mutect2, varscan2
- BTBD17 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 57/506 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1326030963, COSV64729145, COSV64729974; called by muse, mutect2, varscan2
- C1QTNF9 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 31/297 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59657760; called by muse, mutect2, varscan2
- CACNA2D1 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs1461155317; called by muse, mutect2, varscan2
- CAPN14 | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 31/286 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.961); catalogued as rs767818823; called by muse, mutect2
- CAPN6 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 65/224 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100136963; called by muse, mutect2, varscan2
- CCDC102B | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 74/467 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.181); catalogued as rs1377824417, COSV60148756; called by muse, mutect2, varscan2
- CD33 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 54/389 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1420963956; called by muse, mutect2, varscan2
- CDR1 | c.617G>A p.W206* | Nonsense Mutation (SNP) | VAF 50/250 reads (20%) | catalogued as rs780819654, COSV65164090; called by muse, varscan2
- CERKL | c.848G>A p.R283Q (on ENST00000339098 / NM_001030311.2; = p.R257Q on NM_201548.5) | Missense Mutation (SNP) | VAF 31/281 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs762961333, COSV59203100; called by muse, mutect2, varscan2
- CFHR5 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV56820648; called by muse, mutect2
- CLEC18C | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 40/509 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.992); catalogued as rs747425645, COSV58499675; called by muse, mutect2
- COBLL1 | c.2855C>T p.S952L (on ENST00000392717; = p.S914L on NM_014900.5) | Missense Mutation (SNP) | VAF 36/318 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs147994447; called by muse, mutect2, varscan2
- COL22A1 | c.3218C>T p.P1073L | Missense Mutation (SNP) | VAF 42/416 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs934820465; called by muse, mutect2
- COL22A1 | c.3217C>T p.P1073S | Missense Mutation (SNP) | VAF 38/360 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs753743439; called by muse, mutect2, varscan2
- COL4A4 | c.1751G>A p.G584E | Missense Mutation (SNP) | VAF 54/387 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61630562, COSV61636519; called by muse, mutect2, varscan2
- CRIP2 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 40/298 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.391); catalogued as rs782276346, COSV61273911; called by muse, mutect2, varscan2
- CSMD3 | c.7733G>A p.G2578E (on ENST00000297405 / NM_001363185.1; = p.G2474E on NM_052900.3) | Missense Mutation (SNP) | VAF 31/307 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52177476; called by muse, mutect2, varscan2
- DCC | c.238C>T p.H80Y | Missense Mutation (SNP) | VAF 71/481 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV59101042, COSV59128876; called by muse, mutect2, varscan2
- DCC | c.2419C>T p.P807S | Missense Mutation (SNP) | VAF 33/353 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100503779; called by muse, mutect2, varscan2
- DNAH5 | c.7771G>A p.E2591K | Missense Mutation (SNP) | VAF 22/221 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs267600363, COSV54238623, COSV99448383; called by muse, mutect2
- DNAH6 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.286); catalogued as rs145235960; called by muse, mutect2, varscan2
- EBF2 | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs201102910, COSV68776774, COSV68779417; called by muse, mutect2, varscan2
- EPB41 | c.782C>G p.S261C (on ENST00000343067 / NM_001166005.2; = p.S52C on NM_004437.4) | Missense Mutation (SNP) | VAF 25/281 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs749414197; called by muse, mutect2
- ERBB4 | c.463C>T p.L155F | Missense Mutation (SNP) | VAF 43/345 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53568906; called by muse, mutect2, varscan2
- FAM111B | c.1895_1896del p.E632Gfs*8 | Frame Shift Del (DEL) | VAF 46/414 reads (11%) | catalogued as rs773944838; called by pindel, varscan2
- FAT4 | c.11152C>T p.R3718C | Missense Mutation (SNP) | VAF 41/415 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs774217003, COSV100629752, COSV58686567; called by muse, mutect2
- FGB | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 31/374 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs121909623, CM003425, COSV57417626; ClinVar: other / uncertain significance; called by muse, mutect2
- FLT3 | c.2938G>A p.D980N | Missense Mutation (SNP) | VAF 37/341 reads (11%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV99608766; called by muse, mutect2, varscan2
- GABRB1 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 40/456 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.196); catalogued as rs1255847912, COSV54974161; called by muse, mutect2
- GABRB1 | c.1255G>T p.D419Y | Missense Mutation (SNP) | VAF 66/519 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV54982579; called by muse, mutect2, varscan2
- GAD1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 51/414 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as rs150945113; called by muse, mutect2, varscan2
- GDF1 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 48/467 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.463); catalogued as rs1396826999, COSV99440834; called by muse, mutect2, varscan2
- GIMD1 | c.313C>T p.L105F | Missense Mutation (SNP) | VAF 22/424 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs186219650; called by muse, mutect2
- GLP1R | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 34/402 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.293); catalogued as rs937676680; called by muse, mutect2
- GLRB | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1287910151, COSV52414608; called by muse, mutect2
- GPATCH8 | c.623+1G>A p.X208_splice | Splice Site (SNP) | VAF 36/178 reads (20%) | catalogued as COSV59193106; called by muse, mutect2, varscan2
- GPR12 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 41/449 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as COSV67344965; called by muse, mutect2
- GRIK4 | c.2357G>A p.G786E | Missense Mutation (SNP) | VAF 28/266 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70806039; called by muse, mutect2, varscan2
- HHIP | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 22/338 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs369873424; called by muse, mutect2
- IBSP | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 36/474 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs748954490, COSV56894710, COSV56896288; called by muse, mutect2
- INAVA | c.1264C>T p.P422S | Missense Mutation (SNP) | VAF 45/419 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV66257120; called by muse, mutect2, varscan2
- ITGA1 | c.1516G>A p.D506N | Missense Mutation (SNP) | VAF 35/321 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1196274978; called by muse, mutect2, varscan2
- JADE1 | c.1354C>T p.Q452* | Nonsense Mutation (SNP) | VAF 44/322 reads (14%) | catalogued as COSV99886482; called by muse, mutect2, varscan2
- KCNQ2 | c.473G>A p.R158K | Missense Mutation (SNP) | VAF 65/582 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV60432728; called by muse, mutect2, varscan2
- KIAA1841 | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 25/325 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as COSV99693538; called by muse, mutect2
- LCK | c.11G>A p.G4D | Missense Mutation (SNP) | VAF 25/304 reads (8%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.013); catalogued as COSV60741269; called by muse, mutect2
- LINGO2 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 48/508 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58059759; called by muse, mutect2
- LPAR1 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 55/440 reads (13%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.925); catalogued as rs745864585, COSV62690884; called by muse, mutect2, varscan2
- LRRC3 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 61/518 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.225); catalogued as rs1281636548; called by muse, mutect2, varscan2
- LRTM1 | c.889G>A p.G297R | Missense Mutation (SNP) | VAF 82/494 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867274375; called by muse, mutect2, varscan2
- MACF1 | c.17998C>T p.L6000F (on ENST00000372915; = p.L4045F on NM_012090.5) | Missense Mutation (SNP) | VAF 33/389 reads (8%) | catalogued as rs1271350869; called by muse, mutect2
- MED12L | c.6383C>T p.S2128F | Missense Mutation (SNP) | VAF 48/290 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV99177446; called by muse, varscan2
- MFSD4A | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 67/491 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747036662; called by muse, mutect2, varscan2
- MGAM | c.3997C>T p.R1333W | Missense Mutation (SNP) | VAF 46/440 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs184974986; called by muse, mutect2, varscan2
- MROH2B | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV68183656; called by muse, mutect2, varscan2
- MUC16 | c.36445C>T p.R12149C | Missense Mutation (SNP) | VAF 22/390 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.952); catalogued as rs150243586, COSV67467701; called by muse, mutect2
- MYO1A | c.1725G>A p.M575I | Missense Mutation (SNP) | VAF 38/424 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55655730; called by muse, mutect2
- MYO3A | c.1957C>G p.H653D | Missense Mutation (SNP) | VAF 46/366 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV56320437; called by muse, mutect2
- NBEA | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 27/280 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.971); catalogued as COSV100079694; called by muse, mutect2
- NEB | c.19220G>A p.R6407Q | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.703); catalogued as rs745615279, COSV51441238, COSV51460697; called by muse, mutect2
- NHS | c.2189C>A p.P730Q | Missense Mutation (SNP) | VAF 64/259 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66273206; called by muse, mutect2, varscan2
- NLRP11 | c.2276G>A p.R759K | Missense Mutation (SNP) | VAF 47/517 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs1568629768, COSV100789730, COSV64085509; called by muse, mutect2
- OR10H5 | c.424A>C p.T142P | Missense Mutation (SNP) | VAF 52/525 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.244); catalogued as COSV58277557; called by muse, mutect2, varscan2
- OR51G2 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 55/362 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as rs199695370, COSV58991753; called by muse, mutect2, varscan2
- OR6C75 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as COSV58551492; called by muse, mutect2
- OR6M1 | c.850C>A p.P284T | Missense Mutation (SNP) | VAF 45/308 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773450436; called by muse, mutect2, varscan2
- PADI3 | c.1885A>G p.T629A | Missense Mutation (SNP) | VAF 41/407 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as rs528253540; called by muse, mutect2, varscan2
- PAPPA2 | c.2434G>A p.D812N | Missense Mutation (SNP) | VAF 35/262 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62778463; called by muse, mutect2, varscan2
- PARD3B | c.3380C>T p.P1127L (on ENST00000406610 / NM_001302769.2; = p.P1058L on NM_057177.7) | Missense Mutation (SNP) | VAF 82/484 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV62525992; called by muse, mutect2, varscan2
- PCSK5 | c.3940G>A p.E1314K | Missense Mutation (SNP) | VAF 43/431 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs755978345, COSV70450087; called by muse, mutect2
- PCYOX1L | c.941C>T p.T314I | Missense Mutation (SNP) | VAF 53/419 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV51002436; called by muse, mutect2, varscan2
- PENK | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 56/485 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.825); catalogued as rs1377419372, COSV59240662, COSV59242614; called by muse, mutect2, varscan2
- PHLDB2 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 41/367 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.915); catalogued as rs776660980; called by muse, mutect2, varscan2
- PKHD1L1 | c.1444C>T p.R482* | Nonsense Mutation (SNP) | VAF 39/344 reads (11%) | catalogued as rs767357107, COSV65741697, COSV65752389; called by muse, mutect2, varscan2
- PKHD1L1 | c.6963G>A p.W2321* | Nonsense Mutation (SNP) | VAF 31/269 reads (12%) | catalogued as rs1279590619; called by muse, mutect2, varscan2
- PLA2G4E | c.1472G>A p.R491K | Missense Mutation (SNP) | VAF 41/278 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV68150030; called by muse, mutect2, varscan2
- PLCH1 | c.2357G>A p.G786E (on ENST00000340059 / NM_001130960.2; = p.G798E on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58197101; called by muse, mutect2, varscan2
- PLXNA4 | c.4007G>T p.R1336L | Missense Mutation (SNP) | VAF 32/264 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV58102339; called by muse, mutect2, varscan2
- PPFIA3 | c.811G>A p.G271S | Missense Mutation (SNP) | VAF 56/464 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs747377137; called by muse, mutect2, varscan2
- PRAMEF6 | c.1160G>A p.G387E | Missense Mutation (SNP) | VAF 34/490 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs947897387; called by muse, mutect2
- PRUNE2 | c.6328G>A p.D2110N | Missense Mutation (SNP) | VAF 41/287 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.75); catalogued as rs752463766, COSV65046335; called by muse, mutect2, varscan2
- RAD51AP2 | c.1448G>A p.G483E | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.015); catalogued as rs778053752; called by muse, mutect2, varscan2
- RARS1 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 46/355 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV51563144; called by muse, mutect2, varscan2
- RNF144A | c.523A>T p.M175L | Missense Mutation (SNP) | VAF 35/225 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV57981418; called by muse, mutect2, varscan2
- ROBO2 | c.3233C>A p.P1078Q | Missense Mutation (SNP) | VAF 60/566 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs374166639, COSV59894429; called by muse, mutect2
- RREB1 | c.1174C>T p.Q392* | Nonsense Mutation (SNP) | VAF 73/512 reads (14%) | catalogued as COSV58561026, COSV58562521; called by muse, mutect2, varscan2
- RSPH10B | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1413569549; called by muse, mutect2
- SCARA3 | c.1577G>A p.G526D | Missense Mutation (SNP) | VAF 66/465 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769764877; called by muse, mutect2, varscan2
- SCN11A | c.5234G>A p.R1745Q | Missense Mutation (SNP) | VAF 48/429 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762191660, COSV56567167; called by muse, mutect2, varscan2
- SCPEP1 | c.1091C>T p.T364M | Missense Mutation (SNP) | VAF 54/405 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs755738485; called by muse, mutect2, varscan2
- SELP | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 63/429 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs866338602; called by muse, mutect2, varscan2
- SEMG2 | c.1484C>T p.S495F | Missense Mutation (SNP) | VAF 42/401 reads (10%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.995); catalogued as COSV65647850; called by muse, mutect2, varscan2
- SESN2 | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 48/341 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1430082772; called by muse, mutect2, varscan2
- SLC2A7 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 60/393 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs867640677; called by muse, mutect2, varscan2
- SLC37A1 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 57/376 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as COSV61402582; called by muse, mutect2, varscan2
- SLC46A2 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 82/516 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs777663312, COSV65289968; called by muse, mutect2, varscan2
- SLC9A3 | c.2383C>T p.P795S | Missense Mutation (SNP) | VAF 49/502 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs1208508793; called by muse, mutect2
- SLCO6A1 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 20/304 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV65811703; called by muse, mutect2
- SPARCL1 | c.1160G>A p.R387K | Missense Mutation (SNP) | VAF 33/341 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs775150397, COSV56803956, COSV56805340; called by muse, mutect2, varscan2
- SRSF6 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 27/279 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs866504121, COSV99719743; called by muse, mutect2, varscan2
- STAB1 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 53/345 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs773609374, COSV58743889; called by muse, mutect2, varscan2
- SULT1C3 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 43/308 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as COSV100227329, COSV104411586; called by muse, mutect2
- SYCP1 | c.2411C>T p.P804L | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs868681665, COSV101050807; called by muse, mutect2, varscan2
- SYCP2 | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 33/317 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as COSV62770077; called by muse, mutect2, varscan2
- SYT10 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 45/336 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as rs866874853, COSV104391111, COSV57337722; called by muse, mutect2, varscan2
- TAF11L2 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 39/376 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.176); catalogued as rs1198394268; called by muse, mutect2, varscan2
- TMEM144 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.553); catalogued as COSV99647023; called by muse, mutect2, varscan2
- TNFSF12 | c.697C>T p.H233Y | Missense Mutation (SNP) | VAF 49/435 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.383); catalogued as COSV53431691, COSV99547094; called by muse, mutect2, varscan2
- TRANK1 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 52/404 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as rs868862203, COSV57141447; called by muse, mutect2, varscan2
- TTC14 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 38/302 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756345469; called by muse, mutect2, varscan2
- TTN | c.66458G>A p.G22153E (on ENST00000591111; = p.G14729E on NM_003319.4) | Missense Mutation (SNP) | VAF 44/370 reads (12%) | PolyPhen benign (0.204); catalogued as COSV100604409; called by muse, mutect2, varscan2
- TTN | c.14665G>A p.E4889K (on ENST00000591111; = p.E3962K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/452 reads (10%) | PolyPhen benign (0.011); catalogued as COSV100620259; called by muse, mutect2, varscan2
- UBOX5 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 51/409 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1219213543; called by muse, mutect2, varscan2
- UGGT1 | c.2743C>T p.H915Y | Missense Mutation (SNP) | VAF 23/219 reads (11%) | SIFT tolerated (0.96); PolyPhen benign (0.013); catalogued as rs1405301985; called by muse, mutect2, varscan2
- ZBED1 | c.839C>A p.S280Y | Missense Mutation (SNP) | VAF 100/757 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV100586146; called by muse, mutect2, varscan2
- ZGLP1 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 44/321 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.745); catalogued as rs1405469204; called by muse, mutect2, varscan2
- ZNF229 | c.1363C>T p.H455Y | Missense Mutation (SNP) | VAF 40/393 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs868366951; called by muse, mutect2, varscan2
- ABCB1 | c.380T>C p.V127A | Missense Mutation (SNP) | VAF 55/373 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- ACE | c.2407C>T p.P803S | Missense Mutation (SNP) | VAF 54/381 reads (14%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- ACOD1 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 60/448 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ACRBP | c.1421C>A p.T474N | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- ACRBP | c.1193C>T p.T398I | Missense Mutation (SNP) | VAF 38/328 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADCY7 | c.3067G>A p.E1023K | Missense Mutation (SNP) | VAF 40/249 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ADGRV1 | c.3676C>T p.L1226F | Missense Mutation (SNP) | VAF 35/339 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- AGFG1 | c.1348C>A p.P450T | Missense Mutation (SNP) | VAF 33/305 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.432); called by mutect2, varscan2
- AIPL1 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 67/402 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALMS1 | c.8032C>T p.P2678S | Missense Mutation (SNP) | VAF 38/430 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.612); called by muse, mutect2
- AQP4 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 35/385 reads (9%) | SIFT tolerated (0.98); PolyPhen benign (0.087); called by muse, mutect2
- ATP8A2 | c.3449C>T p.S1150F | Missense Mutation (SNP) | VAF 41/364 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AXL | c.2503G>A p.G835R (on ENST00000301178 / NM_021913.5; = p.G826R on NM_001699.6) | Missense Mutation (SNP) | VAF 54/417 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BMP2K | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 20/315 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BRWD1 | c.6125C>G p.S2042C | Missense Mutation (SNP) | VAF 57/380 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- C12orf56 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 36/428 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2
- C5AR2 | c.721G>A p.G241R | Missense Mutation (SNP) | VAF 49/452 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CA4 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 50/334 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CCDC157 | c.437G>A p.R146K | Missense Mutation (SNP) | VAF 18/336 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CCN4 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 31/278 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCSER1 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 36/326 reads (11%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDH8 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 40/470 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- CELSR3 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 55/502 reads (11%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CLASP2 | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 42/279 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- CLASRP | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 53/399 reads (13%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- CLPB | c.1990C>T p.P664S | Missense Mutation (SNP) | VAF 38/309 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- CNDP1 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.458); called by muse, varscan2
- CNTN1 | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 51/377 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- COA5 | c.179C>A p.S60* | Nonsense Mutation (SNP) | VAF 24/267 reads (9%) | called by muse, mutect2
- COL21A1 | c.1472G>A p.G491E | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CSMD1 | c.6001T>G p.C2001G (on ENST00000520002; = p.C2000G on NM_033225.6) | Missense Mutation (SNP) | VAF 45/355 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CT83 | c.28A>C p.S10R | Missense Mutation (SNP) | VAF 54/181 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- DIDO1 | c.2398C>T p.P800S | Missense Mutation (SNP) | VAF 61/368 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- DOCK11 | c.5824C>T p.Q1942* | Nonsense Mutation (SNP) | VAF 50/197 reads (25%) | called by muse, mutect2, varscan2
- DSP | c.5755G>A p.D1919N | Missense Mutation (SNP) | VAF 49/411 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- DSP | c.7946G>A p.R2649K | Missense Mutation (SNP) | VAF 33/346 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- DTWD2 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 38/265 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ELANE | c.66G>A p.G22= | Splice Region (SNP) | VAF 52/408 reads (13%) | called by muse, mutect2, varscan2
- ELL | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 49/689 reads (7%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.541); called by muse, mutect2
- ENPEP | c.2765A>G p.E922G | Missense Mutation (SNP) | VAF 30/350 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.441); called by muse, mutect2
- FAM3B | c.414G>T p.M138I | Missense Mutation (SNP) | VAF 12/352 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.225); called by muse, mutect2
- FAT4 | c.12188C>T p.T4063I | Missense Mutation (SNP) | VAF 35/247 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FKBP5 | c.727T>A p.Y243N | Missense Mutation (SNP) | VAF 34/330 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRMPD1 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 39/310 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- GABRQ | c.1784C>T p.S595F | Missense Mutation (SNP) | VAF 78/280 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- HTR4 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 25/251 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKC | c.157C>A p.Q53K | Missense Mutation (SNP) | VAF 43/328 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- IRAG1 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 54/333 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- ITK | c.1354G>A p.G452R | Missense Mutation (SNP) | VAF 49/388 reads (13%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KAT6B | c.4942C>T p.P1648S | Missense Mutation (SNP) | VAF 37/357 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KBTBD3 | c.1550C>T p.S517F | Missense Mutation (SNP) | VAF 43/272 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF12 | c.90C>T p.L30= | Splice Region (SNP) | VAF 43/365 reads (12%) | called by muse, mutect2, varscan2
- KIF20B | c.3326A>G p.N1109S (on ENST00000371728 / NM_001284259.2; = p.N1069S on NM_016195.4) | Missense Mutation (SNP) | VAF 55/312 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- KLKB1 | c.1857C>A p.D619E | Missense Mutation (SNP) | VAF 36/404 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.201); called by muse, mutect2
- KNDC1 | c.1424C>G p.T475R | Missense Mutation (SNP) | VAF 42/274 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- KRT72 | c.627G>T p.E209D | Missense Mutation (SNP) | VAF 33/244 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KSR1 | c.290G>A p.G97D | Missense Mutation (SNP) | VAF 63/314 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- LAMP5 | c.608T>G p.L203R | Missense Mutation (SNP) | VAF 45/384 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- LCT | c.1357T>A p.F453I | Missense Mutation (SNP) | VAF 43/375 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRATD1 | c.36C>A p.N12K | Missense Mutation (SNP) | VAF 54/409 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- LUC7L | c.226A>G p.K76E | Missense Mutation (SNP) | VAF 10/294 reads (3%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.449); called by muse, mutect2
- LYG2 | c.347G>T p.W116L | Missense Mutation (SNP) | VAF 33/311 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGEC1 | c.1881C>G p.S627R | Missense Mutation (SNP) | VAF 55/253 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- MAPK9 | c.502C>T p.L168F | Missense Mutation (SNP) | VAF 32/435 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- MUC17 | c.3411A>T p.E1137D | Missense Mutation (SNP) | VAF 75/790 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2
- MXRA5 | c.5976G>A p.W1992* | Nonsense Mutation (SNP) | VAF 61/258 reads (24%) | called by muse, mutect2, varscan2
- MYO7B | c.3554G>A p.W1185* | Nonsense Mutation (SNP) | VAF 42/351 reads (12%) | called by muse, mutect2, varscan2
- NUTM1 | c.2458G>A p.E820K | Missense Mutation (SNP) | VAF 53/439 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OAS1 | c.1113T>A p.H371Q | Missense Mutation (SNP) | VAF 44/310 reads (14%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.006); called by mutect2, varscan2
- OBSCN | c.12647C>A p.T4216N | Missense Mutation (SNP) | VAF 46/425 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- OR13C5 | c.346G>A p.G116S | Missense Mutation (SNP) | VAF 25/348 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.019); called by muse, mutect2
- OR14J1 | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 33/239 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR7A5 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 65/442 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- OR7D4 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 52/435 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PADI1 | c.371G>A p.G124D | Missense Mutation (SNP) | VAF 46/330 reads (14%) | SIFT tolerated (0.82); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PCDH18 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 28/385 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.006); called by muse, mutect2
- PCDHA11 | c.2327C>T p.P776L | Missense Mutation (SNP) | VAF 46/492 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.072); called by muse, mutect2
- PCDHB13 | c.1480C>A p.Q494K | Missense Mutation (SNP) | VAF 62/633 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.115); called by muse, mutect2
- PHPT1 | c.100G>C p.G34R | Missense Mutation (SNP) | VAF 27/440 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.096); called by muse, mutect2
- PI4KA | c.5113G>A p.D1705N | Missense Mutation (SNP) | VAF 11/231 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLEKHN1 | c.420dup p.P141Tfs*35 (on ENST00000379409; = p.P141Tfs*148 on NM_032129.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 54/436 reads (12%) | called by mutect2, pindel, varscan2
- POLR3C | c.1190A>G p.K397R | Missense Mutation (SNP) | VAF 46/279 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- POU4F2 | c.637G>A p.V213M | Missense Mutation (SNP) | VAF 48/491 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PPL | c.5017G>A p.E1673K | Missense Mutation (SNP) | VAF 46/347 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PURG | c.103C>A p.Q35K | Missense Mutation (SNP) | VAF 61/374 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PXDN | c.3313C>T p.P1105S | Missense Mutation (SNP) | VAF 76/583 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAB3IP | c.736G>A p.D246N (on ENST00000550536 / NM_175623.4; = p.D230N on NM_022456.5) | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RP1 | c.3792G>A p.W1264* | Nonsense Mutation (SNP) | VAF 54/338 reads (16%) | called by muse, mutect2, varscan2
- RPL18A | c.109C>T p.H37Y | Missense Mutation (SNP) | VAF 68/373 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- RPL5 | c.508G>T p.G170C | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RPS6KA5 | c.2158C>T p.H720Y | Missense Mutation (SNP) | VAF 48/246 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SCN10A | c.1464T>A p.S488= | Splice Region (SNP) | VAF 26/212 reads (12%) | called by muse, mutect2, varscan2
- SCN10A | c.1463C>T p.S488F | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- SCN1B | c.158C>T p.T53I | Missense Mutation (SNP) | VAF 28/399 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2
- SHANK1 | c.3229T>G p.S1077A | Missense Mutation (SNP) | VAF 60/516 reads (12%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC16A12 | c.266G>A p.W89* | Nonsense Mutation (SNP) | VAF 49/303 reads (16%) | called by muse, mutect2, varscan2
- SOBP | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 53/463 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPAG16 | c.1000A>C p.S334R | Missense Mutation (SNP) | VAF 50/287 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPTBN4 | c.5983G>A p.V1995M | Missense Mutation (SNP) | VAF 64/431 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SYNPO2 | c.3395G>A p.W1132* | Nonsense Mutation (SNP) | VAF 26/353 reads (7%) | called by muse, mutect2
- SYNPO2 | c.3396G>A p.W1132* | Nonsense Mutation (SNP) | VAF 26/355 reads (7%) | called by muse, mutect2
- TDRD7 | c.1070G>A p.W357* | Nonsense Mutation (SNP) | VAF 44/361 reads (12%) | called by muse, mutect2, varscan2
- TIMELESS | c.2351A>T p.N784I | Missense Mutation (SNP) | VAF 38/340 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM131L | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 20/305 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- TMEM132B | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 41/453 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMPRSS11B | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 13/303 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TNNT2 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 40/368 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- TRA2B | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 48/347 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIM42 | c.2155C>A p.L719I | Missense Mutation (SNP) | VAF 44/304 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TST | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 71/513 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- TTC14 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 38/300 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTC24 | c.1492C>T p.H498Y | Missense Mutation (SNP) | VAF 39/296 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.50950G>A p.G16984R (on ENST00000591111; = p.G9560R on NM_003319.4) | Missense Mutation (SNP) | VAF 54/491 reads (11%) | PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- UBC | c.35C>T p.T12I | Missense Mutation (SNP) | VAF 28/274 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- URB1 | c.3457C>T p.L1153F | Missense Mutation (SNP) | VAF 48/444 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- USP6 | c.2947G>A p.E983K | Missense Mutation (SNP) | VAF 42/266 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- VNN2 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 34/348 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2
- ZCCHC4 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 33/413 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF221 | c.1246C>T p.H416Y | Missense Mutation (SNP) | VAF 34/378 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF445 | c.1328del p.G443Afs*12 | Frame Shift Del (DEL) | VAF 51/440 reads (12%) | called by pindel, varscan2*
- ABI1 | c.165C>T p.T55= | Silent (SNP) | VAF 49/341 reads (14%) | catalogued as COSV61019387; called by muse, mutect2, varscan2
- ACKR3 | c.7C>T p.L3= | Silent (SNP) | VAF 30/212 reads (14%) | called by muse, mutect2, varscan2
- ACP2 | c.606C>T p.T202= | Silent (SNP) | VAF 62/417 reads (15%) | catalogued as rs761597969; called by muse, mutect2, varscan2
- ADA2 | c.240C>T p.F80= | Silent (SNP) | VAF 35/364 reads (10%) | called by muse, mutect2, varscan2
- ADCY3 | c.39G>T p.S13= | Silent (SNP) | VAF 46/349 reads (13%) | called by muse, mutect2, varscan2
- ANO2 | c.595T>C p.L199= (on ENST00000356134 / NM_001278597.3; = p.L203= on NM_001278596.3) | Silent (SNP) | VAF 32/292 reads (11%) | called by mutect2, varscan2
- AP3B2 | c.2013G>A p.K671= | Silent (SNP) | VAF 33/318 reads (10%) | called by muse, mutect2
- ARHGAP31 | c.3685C>T p.L1229= | Silent (SNP) | VAF 49/452 reads (11%) | called by muse, mutect2, varscan2
- ARVCF | c.585C>T p.P195= | Silent (SNP) | VAF 53/626 reads (8%) | called by muse, mutect2
- ASB2 | c.1485C>T p.F495= | Silent (SNP) | VAF 47/278 reads (17%) | catalogued as rs547067875; called by muse, mutect2, varscan2
- ASL | c.870C>T p.P290= | Silent (SNP) | VAF 53/372 reads (14%) | catalogued as rs764804216, COSV59188730; called by muse, mutect2, varscan2
- BDP1 | c.6814C>T p.L2272= | Silent (SNP) | VAF 28/246 reads (11%) | called by muse, mutect2, varscan2
- BEND6 | c.12C>T p.I4= | Silent (SNP) | VAF 21/170 reads (12%) | catalogued as rs762825918, COSV66068322, COSV66070237; called by muse, mutect2, varscan2
- BEST2 | c.186C>T p.F62= | Silent (SNP) | VAF 51/312 reads (16%) | catalogued as rs772723089, COSV50361444, COSV99244684; called by muse, mutect2, varscan2
- BRD1 | c.3138C>T p.V1046= (on ENST00000216267 / NM_001349940.1; = p.V1177= on NM_001304808.3) | Silent (SNP) | VAF 38/363 reads (10%) | called by muse, mutect2, varscan2
- C4BPA | c.1608C>T p.P536= | Silent (SNP) | VAF 20/232 reads (9%) | called by muse, mutect2, varscan2
- CADPS | c.1029G>A p.L343= | Silent (SNP) | VAF 48/356 reads (13%) | called by muse, mutect2, varscan2
- CAPN11 | c.2112C>T p.F704= | Silent (SNP) | VAF 18/269 reads (7%) | called by muse, mutect2
- CCDC157 | c.438G>A p.R146= | Silent (SNP) | VAF 18/340 reads (5%) | called by muse, mutect2
- CKMT1B | c.777G>A p.L259= | Silent (SNP) | VAF 24/306 reads (8%) | called by muse, varscan2
- CLSTN2 | c.2589C>T p.I863= | Silent (SNP) | VAF 56/469 reads (12%) | called by muse, mutect2, varscan2
- CNGB3 | c.651C>G p.L217= | Silent (SNP) | VAF 44/280 reads (16%) | catalogued as rs1192678789, COSV60684465, COSV60687354; called by muse, mutect2, varscan2
- COL4A4 | c.2241C>A p.P747= | Silent (SNP) | VAF 58/426 reads (14%) | catalogued as rs374510402; called by muse, mutect2, varscan2
- CSF3R | c.2451C>T p.L817= | Silent (SNP) | VAF 51/471 reads (11%) | catalogued as rs374780980, COSV100117645; called by muse, mutect2, varscan2
- CXCR1 | c.51C>T p.F17= | Silent (SNP) | VAF 44/375 reads (12%) | catalogued as rs1490609886, COSV99826275; called by muse, mutect2, varscan2
- DRD3 | c.426G>A p.T142= | Silent (SNP) | VAF 59/412 reads (14%) | catalogued as rs375820318; called by muse, mutect2, varscan2
- EIPR1 | c.1095C>T p.S365= | Silent (SNP) | VAF 58/448 reads (13%) | called by muse, mutect2, varscan2
- FAM131A | c.123C>T p.S41= | Silent (SNP) | VAF 63/453 reads (14%) | called by muse, mutect2, varscan2
- FAM193A | c.150C>T p.T50= | Silent (SNP) | VAF 31/404 reads (8%) | catalogued as COSV100218526; called by muse, mutect2
- FAM71A | c.1089C>T p.S363= | Silent (SNP) | VAF 64/415 reads (15%) | catalogued as COSV54238068; called by muse, mutect2, varscan2
- FAM81A | c.519G>A p.T173= | Silent (SNP) | VAF 24/306 reads (8%) | catalogued as rs776653049, COSV55676896; called by muse, mutect2
- FAT2 | c.2706C>T p.G902= | Silent (SNP) | VAF 45/514 reads (9%) | catalogued as rs1004929668, COSV55817381; called by muse, mutect2
- FBP2 | c.210G>A p.E70= | Silent (SNP) | VAF 31/323 reads (10%) | called by muse, mutect2
- FCRL5 | c.78C>T p.F26= | Silent (SNP) | VAF 31/275 reads (11%) | catalogued as COSV100708877, COSV62521745; called by muse, mutect2, varscan2
- FOXI1 | c.417A>G p.A139= | Silent (SNP) | VAF 47/529 reads (9%) | called by muse, mutect2
- GAL3ST3 | c.939C>T p.G313= | Silent (SNP) | VAF 19/109 reads (17%) | catalogued as rs962557859; called by muse, mutect2, varscan2
- GLRA1 | c.795C>T p.L265= | Silent (SNP) | VAF 40/375 reads (11%) | called by muse, mutect2, varscan2
- GRIA1 | c.2649C>T p.F883= | Silent (SNP) | VAF 30/352 reads (9%) | catalogued as rs867734929, COSV53603934, COSV53620518; called by muse, mutect2
- GUCY1A1 | c.1995C>T p.N665= | Silent (SNP) | VAF 38/464 reads (8%) | called by muse, mutect2
- HYKK | c.402C>T p.I134= | Silent (SNP) | VAF 43/304 reads (14%) | catalogued as rs768667853, COSV100856477; called by muse, mutect2, varscan2
- IGHG2 | c.204G>A p.V68= | Silent (SNP) | VAF 43/398 reads (11%) | called by muse, mutect2, varscan2
- IL6ST | c.1248C>T p.I416= | Silent (SNP) | VAF 31/316 reads (10%) | catalogued as rs961747376; called by muse, mutect2
- IRS2 | c.1167C>G p.P389= | Silent (SNP) | VAF 16/169 reads (9%) | called by muse, mutect2
- ISX | c.612C>T p.L204= | Silent (SNP) | VAF 44/411 reads (11%) | catalogued as rs376456588; called by muse, mutect2, varscan2
- JAKMIP1 | c.1515C>T p.L505= | Silent (SNP) | VAF 44/461 reads (10%) | called by muse, mutect2
- KBTBD3 | c.1551C>T p.S517= | Silent (SNP) | VAF 43/276 reads (16%) | catalogued as rs955987666; called by muse, mutect2, varscan2
- KCNH7 | c.1884A>C p.V628= | Silent (SNP) | VAF 55/354 reads (16%) | called by muse, mutect2, varscan2
- KIR2DL1 | c.765C>T p.I255= | Silent (SNP) | VAF 31/422 reads (7%) | called by muse, mutect2
- KIRREL1 | c.2016C>T p.A672= | Silent (SNP) | VAF 49/486 reads (10%) | called by muse, mutect2, varscan2
- KMT2B | c.1431C>T p.S477= | Silent (SNP) | VAF 68/654 reads (10%) | called by muse, mutect2
- KRI1 | c.819C>T p.V273= | Silent (SNP) | VAF 33/325 reads (10%) | called by muse, mutect2
- LGSN | c.1386C>T p.A462= | Silent (SNP) | VAF 47/355 reads (13%) | catalogued as COSV65726367; called by muse, mutect2, varscan2
- MACF1 | c.17997C>T p.V5999= (on ENST00000372915; = p.V4044= on NM_012090.5) | Silent (SNP) | VAF 36/394 reads (9%) | catalogued as rs200132996; called by muse, mutect2
- MAGEL2 | c.1665G>A p.P555= | Silent (SNP) | VAF 61/412 reads (15%) | catalogued as rs768084923, COSV100046094; called by muse, mutect2, varscan2
- MGA | c.5607A>G p.Q1869= (on ENST00000219905 / NM_001164273.1; = p.Q1660= on NM_001080541.2) | Silent (SNP) | VAF 41/410 reads (10%) | catalogued as rs752129722; called by muse, mutect2, varscan2
- MUC16 | c.42558C>T p.L14186= | Silent (SNP) | VAF 22/278 reads (8%) | catalogued as rs752579751; called by muse, mutect2
- MUC3A | c.8847C>T p.S2949= | Silent (SNP) | VAF 42/578 reads (7%) | catalogued as rs1489857122; called by muse, mutect2
- MUCL3 | c.1539C>T p.I513= (on ENST00000304311; = p.I1389= on NM_080870.4) | Silent (SNP) | VAF 53/458 reads (12%) | called by muse, mutect2, varscan2
- MYO9B | c.5289C>T p.P1763= | Silent (SNP) | VAF 25/206 reads (12%) | called by muse, mutect2, varscan2
- NOS1 | c.2718C>T p.T906= | Silent (SNP) | VAF 45/375 reads (12%) | catalogued as rs201696256, COSV57608852; called by muse, mutect2, varscan2
- NPTN | c.396C>T p.S132= | Silent (SNP) | VAF 46/337 reads (14%) | called by muse, mutect2, varscan2
- OR10T2 | c.237C>T p.I79= | Silent (SNP) | VAF 47/335 reads (14%) | catalogued as COSV100554812, COSV57782774; called by muse, mutect2, varscan2
- OR10X1 | c.231C>T p.L77= | Silent (SNP) | VAF 35/398 reads (9%) | catalogued as COSV63767141; called by muse, mutect2
- OR2T6 | c.432C>T p.I144= | Silent (SNP) | VAF 85/605 reads (14%) | catalogued as COSV100861605; called by muse, mutect2, varscan2
- OTOS | c.132C>T p.T44= | Silent (SNP) | VAF 36/346 reads (10%) | catalogued as rs773050122; called by muse, mutect2, varscan2
- P3H3 | c.1149C>T p.S383= | Silent (SNP) | VAF 29/290 reads (10%) | catalogued as rs1555121491, COSV51835210; called by muse, mutect2, varscan2
- PAK5 | c.1191G>A p.T397= | Silent (SNP) | VAF 49/491 reads (10%) | catalogued as COSV62024913; called by muse, mutect2, varscan2
- PCDH12 | c.1497C>T p.I499= | Silent (SNP) | VAF 41/506 reads (8%) | called by muse, mutect2
- PDE4A | c.1473G>A p.E491= (on ENST00000380702 / NM_001111307.2; = p.E252= on NM_006202.3) | Silent (SNP) | VAF 16/212 reads (8%) | called by muse, mutect2
- PKP4 | c.1599C>T p.V533= | Silent (SNP) | VAF 43/321 reads (13%) | called by muse, mutect2, varscan2
- PLEC | c.2166C>T p.A722= (on ENST00000322810 / NM_201380.4; = p.A612= on NM_000445.5) | Silent (SNP) | VAF 55/381 reads (14%) | called by muse, mutect2, varscan2
- PPFIA3 | c.810G>A p.L270= | Silent (SNP) | VAF 55/466 reads (12%) | called by muse, mutect2, varscan2
- PPP1R17 | c.75C>T p.S25= | Silent (SNP) | VAF 50/299 reads (17%) | called by muse, mutect2, varscan2
- PRDX4 | c.465C>T p.T155= | Silent (SNP) | VAF 55/219 reads (25%) | called by muse, mutect2, varscan2
- PROM2 | c.459C>T p.A153= | Silent (SNP) | VAF 54/364 reads (15%) | catalogued as rs1558740445, COSV100469024; called by muse, mutect2, varscan2
- RBM24 | c.279G>A p.R93= (on ENST00000379052 / NM_001143942.2; = p.R48= on NM_153020.2) | Silent (SNP) | VAF 24/211 reads (11%) | called by muse, mutect2, varscan2
- RHBDF1 | c.573C>T p.S191= | Silent (SNP) | VAF 62/462 reads (13%) | catalogued as rs1473621997; called by muse, mutect2, varscan2
- SACS | c.3540C>T p.L1180= | Silent (SNP) | VAF 74/432 reads (17%) | called by muse, mutect2, varscan2
- SCN1B | c.159C>T p.T53= | Silent (SNP) | VAF 27/396 reads (7%) | called by muse, mutect2
- SECISBP2 | c.1164T>A p.S388= | Silent (SNP) | VAF 19/299 reads (6%) | called by muse, mutect2
- SEMA4D | c.2229C>T p.F743= | Silent (SNP) | VAF 46/370 reads (12%) | called by muse, mutect2, varscan2
- SLC7A14 | c.1845C>T p.I615= | Silent (SNP) | VAF 77/481 reads (16%) | called by muse, mutect2, varscan2
- SLC9C2 | c.879G>A p.P293= | Silent (SNP) | VAF 22/264 reads (8%) | catalogued as rs749628917, COSV62945519; called by muse, mutect2
- SPAG16 | c.879G>A p.Q293= | Silent (SNP) | VAF 27/336 reads (8%) | called by muse, mutect2
- STAT2 | c.2004C>T p.I668= | Silent (SNP) | VAF 36/329 reads (11%) | called by muse, mutect2, varscan2
- TAC3 | c.9C>T p.I3= | Silent (SNP) | VAF 23/213 reads (11%) | called by muse, mutect2, varscan2
- TAF4 | c.1968C>T p.F656= | Silent (SNP) | VAF 20/294 reads (7%) | catalogued as COSV53341734; called by muse, mutect2
- TBC1D9 | c.3565C>T p.L1189= | Silent (SNP) | VAF 40/458 reads (9%) | called by muse, mutect2
- TENM2 | c.2304C>T p.R768= (on ENST00000518659 / NM_001122679.2; = p.R536= on NM_001080428.3) | Silent (SNP) | VAF 39/439 reads (9%) | catalogued as rs747088134, COSV69122059; called by muse, mutect2
- THBS3 | c.2112C>T p.D704= | Silent (SNP) | VAF 31/323 reads (10%) | called by muse, mutect2
- TINAG | c.1392C>T p.I464= | Silent (SNP) | VAF 30/365 reads (8%) | catalogued as rs544720758, COSV52511690; called by muse, mutect2
- TLL2 | c.2292C>T p.L764= | Silent (SNP) | VAF 19/206 reads (9%) | called by muse, mutect2
- TRIM24 | c.858C>T p.F286= | Silent (SNP) | VAF 15/204 reads (7%) | catalogued as rs1402671538; called by muse, mutect2
- TRIML2 | c.513G>A p.E171= | Silent (SNP) | VAF 28/345 reads (8%) | called by muse, mutect2
- UBA2 | c.1596C>T p.I532= | Silent (SNP) | VAF 33/244 reads (14%) | catalogued as COSV55829801; called by muse, mutect2, varscan2
- UBOX5 | c.837C>T p.P279= | Silent (SNP) | VAF 50/407 reads (12%) | called by muse, mutect2, varscan2
- USH2A | c.282C>T p.H94= | Silent (SNP) | VAF 44/363 reads (12%) | catalogued as COSV100234131; called by muse, mutect2, varscan2
- VNN1 | c.879G>A p.K293= | Silent (SNP) | VAF 37/287 reads (13%) | catalogued as rs754857968; called by muse, mutect2, varscan2
- VPS18 | c.774C>T p.F258= | Silent (SNP) | VAF 59/473 reads (12%) | catalogued as COSV55030265; called by muse, mutect2, varscan2
- VPS35L | c.2001G>A p.L667= | Silent (SNP) | VAF 34/307 reads (11%) | called by muse, mutect2, varscan2
- ZEB1 | c.2304G>A p.L768= | Silent (SNP) | VAF 57/411 reads (14%) | catalogued as COSV58046050; called by muse, mutect2, varscan2
- ZFAND1 | c.198C>T p.F66= | Silent (SNP) | VAF 35/315 reads (11%) | called by muse, mutect2, varscan2
- ZNF473 | c.126C>T p.L42= | Silent (SNP) | VAF 29/271 reads (11%) | catalogued as COSV54522477; called by muse, mutect2
- AL132655.6 | chr20:58839703 G>A | 5'Flank (SNP) | VAF 76/436 reads (17%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73852469 C>T | 3'Flank (SNP) | VAF 40/135 reads (30%) | called by muse, mutect2, varscan2
- CDH2 | c.173-22607C>T | Intron (SNP) | VAF 24/312 reads (8%) | called by muse, mutect2
- COL6A2 | c.2461+2692C>T | Intron (SNP) | VAF 42/384 reads (11%) | catalogued as rs145268174, COSV56002720; called by muse, mutect2, varscan2
- FRMPD2 | chr10:48156095 G>A | 3'Flank (SNP) | VAF 17/126 reads (13%) | called by muse, mutect2, varscan2
- TLL1 | c.1158+5032C>T | Intron (SNP) | VAF 33/262 reads (13%) | catalogued as rs764238160; called by muse, mutect2, varscan2
